Somatic mutation profile of tumor specimen HTMCP-03-06-02352-01A (aliquot HTMCP-03-06-02352-01A-01D-9392) from CGCI case HTMCP-03-06-02352, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3.
Specimen HTMCP-03-06-02352-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba49d4bf-9169-4b02-9dca-25785558941c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02352-10A (Blood Derived Normal), aliquot HTMCP-03-06-02352-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5d661b3-eaa9-47c6-9c71-b89bbc69191d

The open-access MAF lists 163 somatic variants for this specimen: 122 protein-altering or splice-affecting, 35 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 35, Nonsense Mutation 13, Splice Region 6, Splice Site 4, Frame Shift Del 4, In Frame Del 2, Intron 2, 5'Flank 1, RNA 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP5 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs766988509, COSV53713412; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 60/98 reads (61%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.715C>G p.H239D | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99685963; called by muse, mutect2, varscan2
- ADCY5 | c.3409G>A p.D1137N | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.174); catalogued as rs372969062; called by muse, mutect2, varscan2
- ALK | c.1045G>T p.V349F | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101201525, COSV101201856; called by muse, mutect2, varscan2
- CEP350 | c.7159G>C p.E2387Q | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV62607861; called by muse, mutect2, varscan2
- CLASRP | c.1099C>G p.P367A | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs767500534; called by muse, mutect2, varscan2
- CRTC3 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV99185617; called by muse, mutect2, varscan2
- CSDE1 | c.926C>G p.T309S (on ENST00000358528 / NM_001007553.3; = p.T278S on NM_007158.6) | Missense Mutation (SNP) | VAF 78/143 reads (55%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); catalogued as COSV54762780; called by muse, mutect2, varscan2
- DHX8 | c.3655C>T p.R1219W | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1276779780, COSV52253929; called by muse, mutect2, varscan2
- DIDO1 | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as rs770549757, COSV56623373, COSV56627673; called by muse, mutect2, varscan2
- DMXL2 | c.326dup p.L109Ffs*15 | Frame Shift Ins (INS) | VAF 12/25 reads (48%) | catalogued as rs752363479; called by mutect2, varscan2
- DNAH6 | c.11794G>A p.E3932K | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as COSV52883168; called by muse, mutect2, varscan2
- DSCAM | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.5); catalogued as COSV68024326; called by muse, mutect2, varscan2
- DSCAML1 | c.5854C>T p.R1952W (on ENST00000321322; = p.R1892W on NM_020693.4) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs201027576, COSV58387248; called by muse, mutect2, varscan2
- EPS8 | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 139/273 reads (51%) | catalogued as rs1027436562; called by muse, mutect2, varscan2
- FLII | c.3396+3C>T | Splice Region (SNP) | VAF 26/59 reads (44%) | catalogued as rs753698988; called by muse, mutect2, varscan2
- GBF1 | c.5509G>A p.E1837K (on ENST00000369983 / NM_001377137.1; = p.E1836K on NM_004193.3) | Missense Mutation (SNP) | VAF 67/107 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs377647711; called by muse, mutect2, varscan2
- GLI2 | c.4592G>A p.R1531Q (on ENST00000361492 / NM_001374353.1; = p.R1548Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.942); catalogued as rs371304728; called by muse, mutect2, varscan2
- GNA11 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV50017281; called by muse, mutect2, varscan2
- KLHL4 | c.1074G>C p.Q358H | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV100909021; called by muse, mutect2, varscan2
- MAMDC4 | c.3229C>T p.Q1077* (on ENST00000445819; = p.Q998* on NM_206920.3) | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs1477746644; called by muse, mutect2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MUC1 | c.3129G>T p.L1043F (on ENST00000611571 / NM_001371720.1; = p.L54F on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.731); catalogued as rs771498973; called by muse, mutect2, varscan2
- MYO1H | c.2278G>A p.V760M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs758689153; called by muse, mutect2, varscan2
- MYO9B | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV68279638, COSV68282188; called by muse, mutect2, varscan2
- NACA | c.-2-7C>T | Splice Region (SNP) | VAF 14/41 reads (34%) | catalogued as rs752271026, COSV100771156; called by muse, mutect2, varscan2
- NBPF20 | c.16619G>C p.R5540T (on ENST00000369373; = p.R5101T on NM_001278267.1) | Missense Mutation (SNP) | VAF 192/804 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.412); catalogued as rs782152276; called by muse, varscan2
- NF1 | c.6428-1G>T p.X2143_splice (on ENST00000358273 / NM_001042492.3; = p.X2122_splice on NM_000267.3) | Splice Site (SNP) | VAF 40/73 reads (55%) | catalogued as CS063347, COSV62202294; called by muse, mutect2, varscan2
- OSBP2 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369146536, COSV60244813; called by muse, mutect2, varscan2
- PITPNM2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54908682; called by muse, mutect2, varscan2
- PIWIL1 | c.1273A>C p.I425L | Missense Mutation (SNP) | VAF 107/310 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1354975357; called by muse, mutect2, varscan2
- PLCG1 | c.488C>G p.S163* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | catalogued as COSV54824146, COSV99718826; called by muse, mutect2, varscan2
- PPFIA2 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778855709, COSV61056853; called by muse, mutect2, varscan2
- PTEN | c.79+5C>G | Splice Region (SNP) | VAF 26/43 reads (60%) | catalogued as rs1564801891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REL | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 107/227 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54368187; called by muse, mutect2, varscan2
- RUNX1T1 | c.1095G>A p.M365I (on ENST00000265814 / NM_001198628.1; = p.M338I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.411); catalogued as rs867558286; called by muse, mutect2, varscan2
- SGK3 | c.1096G>T p.V366F | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.629); catalogued as COSV61896755; called by mutect2, varscan2
- SMAD4 | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 54/106 reads (51%) | catalogued as COSV61696700; called by muse, mutect2, varscan2
- SYNPO2 | c.3050C>T p.T1017M | Missense Mutation (SNP) | VAF 93/173 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as rs769802322, COSV61113001; called by muse, mutect2, varscan2
- TCHH | c.3949G>A p.E1317K | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as rs376568730; called by muse, mutect2, varscan2
- TET3 | c.2656C>T p.R886C | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101328034; called by muse, mutect2, varscan2
- TPO | c.2332G>C p.E778Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV61095286, COSV61099964, COSV61110474; called by muse, mutect2, varscan2
- WDFY4 | c.1068G>T p.K356N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs151002695; called by muse, mutect2, varscan2
- ZHX3 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 115/309 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58382020, COSV58382170; called by muse, mutect2, varscan2
- ZNF157 | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 81/133 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs138071941, COSV100998461; called by muse, mutect2, varscan2
- ADGRD1 | c.402C>G p.F134L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- ALMS1 | c.830_856del p.L277_A285del | In Frame Del (DEL) | VAF 25/127 reads (20%) | called by mutect2, pindel, varscan2
- APBA2 | c.1151C>G p.S384* | Nonsense Mutation (SNP) | VAF 56/183 reads (31%) | called by muse, mutect2, varscan2
- CBX6 | c.1069del p.D357Tfs*22 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- CHGB | c.1698C>A p.Y566* | Nonsense Mutation (SNP) | VAF 61/175 reads (35%) | called by muse, mutect2, varscan2
- CNKSR1 | c.2024C>A p.A675E (on ENST00000374253 / NM_001297647.2; = p.A668E on NM_006314.3) | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL17A1 | c.2071G>T p.V691L | Missense Mutation (SNP) | VAF 86/155 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CUL5 | c.783C>T p.L261= | Splice Region (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- DGKG | c.1601-2A>T p.X534_splice | Splice Site (SNP) | VAF 39/140 reads (28%) | called by muse, mutect2, varscan2
- DLGAP5 | c.1600G>T p.G534W | Missense Mutation (SNP) | VAF 25/324 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DMXL2 | c.3976A>T p.T1326S | Missense Mutation (SNP) | VAF 95/279 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- E2F8 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO38 | c.173_190delinsAAGCT p.R58Qfs*3 | Frame Shift Del (DEL) | VAF 81/155 reads (52%) | called by pindel, varscan2*
- FLNA | c.2680del p.H894Tfs*4 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel
- FMO5 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FRMPD1 | c.3707G>T p.G1236V | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- GAP43 | c.437C>G p.A146G | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.182); called by muse, mutect2
- GFRA1 | c.455A>G p.N152S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GLI3 | c.4266G>C p.K1422N | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HOXD11 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HRC | c.1735G>C p.E579Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HSPA6 | c.1611A>T p.R537S | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); called by muse, mutect2
- IFT122 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGF2R | c.5542G>C p.G1848R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ITGA8 | c.2677T>C p.F893L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ITPR3 | c.5197G>T p.A1733S | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- KANSL1 | c.2704G>C p.D902H (on ENST00000574590 / NM_001193465.2; = p.D903H on NM_015443.4) | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- KIF21A | c.4091C>G p.S1364* (on ENST00000361418 / NM_001378440.1; = p.S1351* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/124 reads (27%) | called by muse, mutect2, varscan2
- KIF4B | c.2697G>C p.Q899H | Missense Mutation (SNP) | VAF 148/253 reads (58%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- LAMA2 | c.5594C>G p.P1865R | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- LAMC2 | c.2179C>T p.Q727* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- LRP1 | c.3060C>G p.F1020L | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LRP2 | c.10548G>T p.Q3516H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEE1 | c.2400_2413del p.E801* | Frame Shift Del (DEL) | VAF 49/112 reads (44%) | called by mutect2, pindel, varscan2
- MUC16 | c.24100T>G p.S8034A | Missense Mutation (SNP) | VAF 128/356 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MUC17 | c.8897G>T p.S2966I | Missense Mutation (SNP) | VAF 307/907 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MUC22 | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 273/382 reads (71%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MUC4 | c.12985G>C p.E4329Q (on ENST00000463781 / NM_018406.7; = p.E93Q on NM_004532.6) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO1H | c.606G>C p.L202F | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBAS | c.333C>T p.I111= | Splice Region (SNP) | VAF 153/312 reads (49%) | called by muse, mutect2, varscan2
- NBN | c.2261G>C p.R754T | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLGN1 | c.1234G>C p.D412H | Missense Mutation (SNP) | VAF 126/490 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NOTCH3 | c.3661G>C p.D1221H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2
- NRP1 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 69/116 reads (59%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- NSD1 | c.8085G>C p.Q2695H | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- NUP188 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NUP98 | c.3269C>T p.P1090L (on ENST00000359171 / NM_001365126.1; = p.P1073L on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5H14 | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 66/261 reads (25%) | called by muse, mutect2, varscan2
- OR8H2 | c.20A>T p.N7I | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- PFKP | c.590T>G p.V197G | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PHF3 | c.3794G>C p.G1265A | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PITPNM2 | c.3070T>A p.F1024I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PLEKHG1 | c.1807C>T p.H603Y | Missense Mutation (SNP) | VAF 100/183 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- PLXNB1 | c.5775G>C p.M1925I | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- PRB3 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 132/292 reads (45%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBL2 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RORC | c.1285+4A>G | Splice Region (SNP) | VAF 17/161 reads (11%) | called by muse, mutect2
- SASH1 | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 70/138 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC5A11 | c.407T>A p.F136Y | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TBC1D12 | c.1520-19_1528del p.X507_splice | Splice Site (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- TBC1D23 | c.1213A>T p.R405W | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNXB | c.8574A>T p.E2858D (on ENST00000647633; = p.E2611D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.174); called by muse, mutect2
- TP53BP1 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 71/186 reads (38%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.4919C>G p.S1640* | Nonsense Mutation (SNP) | VAF 57/86 reads (66%) | called by muse, mutect2, varscan2
- TTN | c.70843G>C p.D23615H (on ENST00000591111; = p.D16191H on NM_003319.4) | Missense Mutation (SNP) | VAF 89/277 reads (32%) | PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- U2SURP | c.90+1G>T p.X30_splice | Splice Site (SNP) | VAF 31/98 reads (32%) | called by muse, mutect2, varscan2
- UBQLN1 | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 90/158 reads (57%) | SIFT tolerated (0.91); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- UPF2 | c.1508_1534del p.A503_E511del | In Frame Del (DEL) | VAF 10/128 reads (8%) | called by mutect2, pindel
- USF3 | c.3544A>G p.K1182E | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- USP47 | c.475A>G p.R159G (on ENST00000399455 / NM_001372095.1; = p.R71G on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- WDFY4 | c.1069G>T p.V357L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WRN | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- XIRP2 | c.4886G>A p.S1629N (on ENST00000628543; = p.S1804N on NM_152381.6) | Missense Mutation (SNP) | VAF 90/243 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZAN | c.1075G>C p.D359H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF687 | c.2189G>C p.R730P | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ZNF99 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 90/270 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AGFG2 | c.654C>G p.V218= | Silent (SNP) | VAF 48/135 reads (36%) | called by muse, mutect2, varscan2
- AKAP6 | c.1581A>T p.S527= | Silent (SNP) | VAF 70/200 reads (35%) | called by muse, mutect2, varscan2
- ATP13A4 | c.753C>G p.L251= | Silent (SNP) | VAF 40/248 reads (16%) | catalogued as COSV55065410, COSV55069576; called by muse, mutect2, varscan2
- BCORL1 | c.804C>T p.L268= | Silent (SNP) | VAF 72/145 reads (50%) | catalogued as rs1025355511, COSV54408098; called by muse, mutect2, varscan2
- CCDC40 | c.1029G>A p.K343= | Silent (SNP) | VAF 19/28 reads (68%) | called by muse, mutect2, varscan2
- CFAP54 | c.6174C>T p.F2058= | Silent (SNP) | VAF 45/153 reads (29%) | called by muse, mutect2, varscan2
- CHL1 | c.2355C>G p.V785= (on ENST00000397491 / NM_001253387.1; = p.V801= on NM_006614.4) | Silent (SNP) | VAF 65/102 reads (64%) | catalogued as COSV56586358; called by muse, mutect2, varscan2
- CNKSR1 | c.1917C>T p.V639= (on ENST00000374253 / NM_001297647.2; = p.V632= on NM_006314.3) | Silent (SNP) | VAF 25/44 reads (57%) | called by muse, mutect2, varscan2
- COL6A3 | c.5802G>A p.L1934= | Silent (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- CSMD1 | c.5970C>A p.G1990= (on ENST00000520002; = p.G1989= on NM_033225.6) | Silent (SNP) | VAF 50/96 reads (52%) | called by muse, mutect2, varscan2
- DNAH6 | c.11907G>A p.L3969= | Silent (SNP) | VAF 45/136 reads (33%) | called by muse, mutect2, varscan2
- EPS8L2 | c.849G>A p.L283= | Silent (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- GOLGA3 | c.1335C>G p.L445= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- GRID2IP | c.3330C>T p.I1110= | Silent (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- HAP1 | c.726C>G p.L242= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as rs1555591237; called by muse, mutect2, varscan2
- HIVEP1 | c.7575G>A p.L2525= | Silent (SNP) | VAF 73/133 reads (55%) | called by muse, mutect2, varscan2
- HSPA6 | c.1609A>C p.R537= | Silent (SNP) | VAF 54/142 reads (38%) | called by muse, mutect2
- KRI1 | c.36G>A p.V12= | Silent (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- LRRC37B | c.2412G>A p.E804= | Silent (SNP) | VAF 66/137 reads (48%) | called by muse, mutect2, varscan2
- LY75 | c.4353A>T p.P1451= | Silent (SNP) | VAF 85/249 reads (34%) | called by muse, mutect2, varscan2
- MAN1B1 | c.147C>T p.F49= | Silent (SNP) | VAF 14/19 reads (74%) | called by muse, varscan2
- MAP3K13 | c.561C>T p.F187= | Silent (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2, varscan2
- MAPKBP1 | c.816G>A p.L272= | Silent (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- MYH9 | c.1620G>A p.K540= | Silent (SNP) | VAF 17/71 reads (24%) | called by muse, mutect2, varscan2
- NLRP2 | c.120G>A p.Q40= | Silent (SNP) | VAF 58/149 reads (39%) | catalogued as rs1412888567, COSV54759407; called by muse, mutect2, varscan2
- NRXN3 | c.3024C>T p.L1008= (on ENST00000335750 / NM_001330195.2; = p.L635= on NM_004796.6) | Silent (SNP) | VAF 66/218 reads (30%) | catalogued as rs564964171; called by muse, mutect2, varscan2
- NYNRIN | c.5274C>T p.F1758= | Silent (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- PMP22 | c.402C>T p.F134= | Silent (SNP) | VAF 45/76 reads (59%) | catalogued as rs536417866; called by muse, mutect2, varscan2
- PTPRB | c.5073T>C p.H1691= | Silent (SNP) | VAF 45/139 reads (32%) | called by muse, mutect2, varscan2
- RXRA | c.393C>T p.T131= | Silent (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- SEMA4B | c.1863C>T p.L621= | Silent (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- SYNPO | c.2451C>A p.V817= (on ENST00000394243 / NM_001166208.2; = p.V573= on NM_007286.6) | Silent (SNP) | VAF 30/50 reads (60%) | called by muse, mutect2, varscan2
- TTLL6 | c.27G>C p.S9= | Silent (SNP) | VAF 49/78 reads (63%) | catalogued as rs1221255779; called by muse, mutect2, varscan2
- UGT2B11 | c.888A>G p.V296= | Silent (SNP) | VAF 112/203 reads (55%) | catalogued as rs752803858; called by muse, mutect2, varscan2
- ZNF816 | c.96G>A p.E32= | Silent (SNP) | VAF 62/184 reads (34%) | catalogued as COSV54410749; called by muse, mutect2, varscan2
- ADGRF5P1 | chr9:62857374 G>A | 3'Flank (SNP) | VAF 133/716 reads (19%) | catalogued as rs1415047157; called by muse, mutect2, varscan2
- C1orf216 | chr1:35720959 C>T | 5'Flank (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- DCHS2 | n.4251_4265del | RNA (DEL) | VAF 42/84 reads (50%) | called by mutect2, pindel, varscan2
- EML3 | c.*149C>T | 3'UTR (SNP) | VAF 5/21 reads (24%) | catalogued as rs937465357; called by muse, mutect2
- MLIP | c.613-11604G>A | Intron (SNP) | VAF 84/254 reads (33%) | called by muse, mutect2, varscan2
- SULF1 | c.2585+1389G>T | Intron (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
